Somatic mutation profile of tumor specimen TCGA-AN-A0FT-01A (aliquot TCGA-AN-A0FT-01A-11W-A050-09) from TCGA case TCGA-AN-A0FT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.8 years (23,300 days).
Specimen TCGA-AN-A0FT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0ec8322-68e2-4ab1-86b7-b128894ea429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FT-10A (Blood Derived Normal), aliquot TCGA-AN-A0FT-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1ee26fc-9573-4821-9f75-daa5af8b5f72

The open-access MAF lists 108 somatic variants for this specimen: 79 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 28, Nonsense Mutation 9, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.5554C>T p.Q1852* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as rs398123991, CM010825, COSV63754977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 250/315 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABR | c.1650G>T p.K550N (on ENST00000302538 / NM_021962.5; = p.K513N on NM_001092.5) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV52145636; called by muse, mutect2, varscan2
- AGFG2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53545191; called by muse, mutect2, varscan2
- AHRR | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs778268200, COSV57086110; called by muse, mutect2, varscan2
- APEH | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99606872; called by muse, mutect2
- ARHGEF26 | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV62846462; called by muse, mutect2, varscan2
- ATP6V0D2 | c.900G>C p.M300I | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs892818661, COSV53414967, COSV53415362; called by muse, mutect2, varscan2
- BCAN | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 101/142 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1481115577, COSV61256851; called by muse, mutect2, varscan2
- BCR | c.900G>C p.Q300H | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.275); catalogued as COSV59931095; called by muse, mutect2, varscan2
- C3orf70 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as COSV100621089; called by muse, mutect2
- CAMSAP2 | c.1232T>G p.I411S (on ENST00000236925 / NM_001297707.2; = p.I400S on NM_203459.3) | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV52670384; called by muse, mutect2, varscan2
- CARD11 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs1016457945, COSV100829054; called by muse, mutect2
- CARMIL3 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1158902521, COSV57727800; called by muse, mutect2, varscan2
- CBL | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs1313093726, COSV50636839; called by muse, mutect2, varscan2
- CCDC171 | c.2477C>A p.T826N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV52641586; called by muse, mutect2, varscan2
- CCDC9B | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV66875441; called by muse, mutect2, varscan2
- CD5L | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as COSV63821511, COSV63821961; called by muse, mutect2, varscan2
- CNNM2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs753065287, COSV63998642; called by muse, mutect2, varscan2
- COLEC12 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 31/215 reads (14%) | catalogued as COSV68370577; called by muse, mutect2, varscan2
- CTDSP1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV56089922; called by muse, mutect2, varscan2
- DCDC1 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs143406648, COSV60862581; called by muse, mutect2
- DHRS13 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV60454446; called by muse, mutect2, varscan2
- DPP6 | c.418G>T p.D140Y (on ENST00000377770 / NM_001364500.2; = p.D78Y on NM_001936.5) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59613303; called by muse, mutect2, varscan2
- ELOVL5 | c.450del p.M150Ifs*2 | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | catalogued as COSV58650519; called by mutect2, pindel, varscan2
- GIMAP8 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs759454503, COSV56231440; called by muse, mutect2, varscan2
- HEY2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV64239889; called by muse, mutect2, varscan2
- IREB2 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV51922647; called by muse, mutect2, varscan2
- KCNH8 | c.2784G>A p.W928* | Nonsense Mutation (SNP) | VAF 19/157 reads (12%) | catalogued as COSV60463768; called by muse, mutect2, varscan2
- KCNN2 | c.981G>A p.W327* (on ENST00000264773; = p.W539* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV53288636; called by muse, mutect2, varscan2
- KRTAP10-2 | c.662C>G p.T221S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV59962118; called by muse, mutect2, varscan2
- LEO1 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV55175752; called by muse, mutect2, varscan2
- LGALSL | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs769810964, COSV53230141; called by muse, mutect2, varscan2
- LNPK | c.99A>T p.E33D | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV55823961; called by muse, mutect2, varscan2
- MOS | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV61336339; called by muse, mutect2, varscan2
- NEDD9 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 33/254 reads (13%) | catalogued as COSV65221088; called by muse, mutect2, varscan2
- OR10H2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 149/723 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs878935884, COSV59945998; called by muse, mutect2, varscan2
- OR10Z1 | c.126T>A p.N42K | Missense Mutation (SNP) | VAF 35/415 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778908; called by muse, mutect2
- OR6Y1 | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100225195; called by muse, mutect2
- PCDHA9 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs781909313, COSV65326566; called by muse, mutect2, varscan2
- PDS5A | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772049125, COSV57825797; called by muse, mutect2, varscan2
- PHLDA1 | c.1168G>C p.G390R | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56997365, COSV99876731; called by muse, mutect2, varscan2
- PITRM1 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99828071; called by muse, mutect2, varscan2
- PLA2G4A | c.558+2T>A p.X186_splice | Splice Site (SNP) | VAF 20/125 reads (16%) | catalogued as COSV66553918; called by muse, mutect2, varscan2
- PLEKHM3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as rs1416993669, COSV66815589; called by muse, mutect2, varscan2
- PRKAA2 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs963948073, COSV64805783; called by muse, mutect2, varscan2
- PTPRS | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs749770933, COSV53619560; called by muse, mutect2, varscan2
- RIN2 | c.654C>G p.F218L (on ENST00000255006 / NM_001242581.1; = p.F169L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/224 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54788053; called by muse, mutect2, varscan2
- SCUBE3 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99233741; called by muse, mutect2
- SORCS1 | c.3266-2A>C p.X1089_splice | Splice Site (SNP) | VAF 49/189 reads (26%) | catalogued as COSV53866367; called by muse, mutect2, varscan2
- SPARCL1 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV56803588; called by muse, mutect2, varscan2
- SSTR2 | c.460A>G p.R154G | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59535211; called by muse, mutect2, varscan2
- SYTL2 | c.1480C>G p.P494A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV60359091; called by mutect2, varscan2
- TDRP | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100138338; called by muse, mutect2, varscan2
- TIMELESS | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780869332, COSV57509359; called by muse, mutect2, varscan2
- TLE6 | c.1592C>T p.P531L (on ENST00000246112 / NM_001143986.2; = p.P408L on NM_024760.3) | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs200522179, COSV53579943; called by muse, mutect2, varscan2
- TPI1 | c.394G>A p.G132R (on ENST00000229270; = p.G95R on NM_000365.6) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99222754; called by muse, mutect2
- TRAF6 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.069); catalogued as rs746111041, COSV61922487; called by muse, mutect2, varscan2
- TRPC7 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.727); catalogued as COSV61457795; called by muse, mutect2, varscan2
- TRPV4 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs140535889; ClinVar: benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TSLP | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV61291649; called by muse, mutect2, varscan2
- TTC12 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100132768, COSV59098114; called by muse, mutect2, varscan2
- TTC14 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56011128; called by muse, mutect2, varscan2
- UBR5 | c.5041A>T p.S1681C | Missense Mutation (SNP) | VAF 287/383 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV55286750; called by muse, varscan2
- USH2A | c.14389G>A p.A4797T | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100227433; called by muse, mutect2
- USH2A | c.5344C>T p.L1782F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV56369056; called by mutect2, varscan2
- VGLL1 | c.223A>T p.M75L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV65703247; called by muse, mutect2, varscan2
- ZC3H11A | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 39/598 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV100142066; called by muse, mutect2
- ZEB1 | c.2075G>A p.G692E | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.617); catalogued as COSV100313424; called by muse, mutect2
- ZFHX4 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.479); catalogued as COSV50797126; called by muse, mutect2, varscan2
- ZNF106 | c.3592C>T p.Q1198* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV55516771; called by muse, mutect2, varscan2
- ZNF324 | c.25T>C p.Y9H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV52180741; called by muse, mutect2, varscan2
- EXOC6 | c.972+2dup p.X324_splice | Splice Site (INS) | VAF 51/190 reads (27%) | called by mutect2, pindel, varscan2
- FBXL6 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- IRX3 | c.379del p.D127Tfs*16 | Frame Shift Del (DEL) | VAF 56/136 reads (41%) | called by mutect2, pindel, varscan2
- NFASC | c.830_831insTA p.I278Tfs*55 (on ENST00000339876 / NM_001378329.1; = p.I289Tfs*55 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 33/167 reads (20%) | called by mutect2, pindel, varscan2
- SHROOM2 | c.2486dup p.R830Afs*8 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- TMEM268 | c.953dup p.R319Efs*27 | Frame Shift Ins (INS) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- TRBV27 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS16 | c.942C>T p.Y314= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs779883064, COSV56989490, COSV99943452; called by muse, mutect2, varscan2
- APOBR | c.921G>A p.G307= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV60490846; called by muse, mutect2, varscan2
- BAIAP2L1 | c.168C>G p.A56= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV50055935; called by muse, mutect2, varscan2
- BEND3 | c.480C>T p.N160= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs377567267, COSV100944522; called by muse, mutect2
- BNC1 | c.2904G>A p.S968= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs1021377126, COSV61757413; called by muse, mutect2, varscan2
- CFAP206 | c.1581G>A p.T527= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs376338058; called by muse, mutect2, varscan2
- CFHR4 | c.1699A>C p.R567= (on ENST00000367416 / NM_001201551.2; = p.R321= on NM_006684.5) | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as rs748147685, COSV99259117; called by muse, mutect2
- CHL1 | c.2241C>T p.Y747= (on ENST00000397491 / NM_001253387.1; = p.Y763= on NM_006614.4) | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV56593380; called by muse, mutect2, varscan2
- CNTNAP5 | c.651C>T p.V217= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101442878, COSV70475975; called by muse, mutect2, varscan2
- CRAMP1 | c.3792C>G p.V1264= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV50188834, COSV50189077; called by muse, mutect2, varscan2
- CYP2S1 | c.660C>T p.Y220= | Silent (SNP) | VAF 101/352 reads (29%) | catalogued as rs770526978, COSV59506104; called by muse, mutect2, varscan2
- DDX58 | c.1581C>T p.D527= | Silent (SNP) | VAF 140/230 reads (61%) | catalogued as COSV65883167, COSV65883510; called by muse, varscan2
- ERG | c.219C>T p.I73= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV55727222; called by muse, mutect2, varscan2
- FLT3 | c.1986C>T p.L662= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV54052845, COSV54054003; called by muse, mutect2, varscan2
- GANAB | c.2127C>T p.P709= | Silent (SNP) | VAF 72/91 reads (79%) | catalogued as COSV60464581; called by muse, mutect2, varscan2
- IWS1 | c.1692C>T p.I564= | Silent (SNP) | VAF 69/192 reads (36%) | catalogued as rs753294967, COSV54868378; called by muse, mutect2, varscan2
- KANK3 | c.1335C>G p.L445= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV58359559, COSV58360134; called by muse, mutect2, varscan2
- KIF1A | c.1014C>T p.Y338= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1237938827, COSV57489021; called by muse, mutect2, varscan2
- KIF21B | c.861C>T p.G287= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs1469476847, COSV59757713; called by muse, mutect2, varscan2
- KIF26B | c.4443C>T p.D1481= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs912633386, COSV63641555; called by muse, mutect2, varscan2
- KRTAP10-7 | c.54C>T p.R18= | Silent (SNP) | VAF 71/190 reads (37%) | catalogued as rs781850911, COSV59110318; called by muse, mutect2, varscan2
- LRP1 | c.10458C>T p.P3486= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs746142668, COSV54511177; called by muse, mutect2, varscan2
- MRPL51 | c.96C>A p.I32= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV57519679; called by muse, mutect2, varscan2
- NR4A1 | c.453C>G p.L151= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54482325; called by muse, mutect2, varscan2
- PLCH1 | c.510G>T p.L170= (on ENST00000340059 / NM_001130960.2; = p.L182= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV58197267; called by muse, mutect2, varscan2
- PLPPR4 | c.1254G>A p.P418= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as rs202142961, COSV64564643; called by muse, mutect2, varscan2
- ST20 | c.207G>T p.T69= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV51912699, COSV51913629, COSV51913808; called by muse, mutect2, varscan2
- ZNF85 | c.414C>G p.L138= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV56021022, COSV56021689; called by muse, mutect2, varscan2
- OBSCN | c.18662-2735G>A | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs764953117, COSV52765673; called by muse, mutect2, varscan2
